Surgical pathology report (de-identified scan), TCGA case TCGA-27-2527, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Milan - Italy, Fondazione IRCCS Instituto Neuroligico C. Besta, specimen TCGA-27-2527-01A (Primary Tumor).

[REDACTED]

[REDACTED]

Ref. Number

[REDACTED]

[REDACTED]

TCGA-27-2527

Gender

[REDACTED]

Birth date

[REDACTED]

Tumor site

Right temporal

Histological diagnosis

Glioblastoma multiforme

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file b6285f33-2e75-4332-abdf-fe14a5c73c15 (TCGA-27-2527.F5F2CBE2-2A67-4CC0-8867-6C96AE009EE3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).